Gene-level copy-number profile of tumor specimen TCGA-FD-A3SJ-01A from TCGA case TCGA-FD-A3SJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.2 years (21,615 days).
Specimen TCGA-FD-A3SJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a45f9b85-53fd-4a0c-8504-b46214076b15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3SJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/65a056d5-624c-4d12-b51a-96b03908eb65

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 3,284; copy number 2: 13,671; copy number 3: 17,260; copy number 4: 10,798; copy number 5: 10,927; copy number 6: 731; copy number 7: 421; copy number 8: 947; copy number 9: 392; copy number 10: 236; copy number 11: 410; copy number 12: 102; copy number 13: 140; copy number 15: 194; copy number 16: 87; copy number 17: 63; copy number 19: 14; copy number 21: 73; copy number 22: 8; copy number 23: 14; copy number 30: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3SJ-01A-12D-A22Y-01): tumor purity 0.46, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:27,638,483–28,727,680, 23 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1.
- chr19:28,606,688–28,615,229, 1 gene: AC079466.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,113 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,800,511–177,437,880, 420 genes, copy number 10–21 (broad region; genes not listed).
- chr1:246,945,547–248,919,946, 110 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:58,159,243–64,347,741, 116 genes, copy number 8–9 (broad region; genes not listed).
- chr2:94,953,161–98,398,601, 128 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:6,148,484–23,202,703, 263 genes, copy number 7–15 (broad region; genes not listed).
- chr3:26,216,322–27,931,579, 21 genes, copy number 8 (within-gene range 5–8): HMGB3P12, VENTXP4, AC099754.1, LRRC3B, NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981.
- chr3:33,496,245–34,677,247, 10 genes, copy number 7 (within-gene range 5–7): CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1.
- chr3:108,032,456–115,721,490, 135 genes, copy number 7 (broad region; genes not listed).
- chr3:115,837,870–115,838,159, 1 gene, copy number 7: RN7SL815P.
- chr3:173,396,284–175,810,548, 10 genes, copy number 7 (within-gene range 5–7): NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3.
- chr4:53,377,839–54,295,272, 1 gene, copy number 8 (within-gene range 6–8): AC058822.1.
- chr4:53,899,871–56,761,485, 69 genes, copy number 8 (broad region; genes not listed).
- chr6:9,124,221–21,602,383, 184 genes, copy number 9–30 (broad region; genes not listed).
- chr6:21,822,536–21,822,737, 1 gene, copy number 22: AL136313.1.
- chr6:23,649,496–24,537,207, 13 genes, copy number 8 (within-gene range 4–8): AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1.
- chr6:62,547,427–63,230,110, 6 genes, copy number 11: AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2.
- chr7:17,299,295–17,680,659, 5 genes, copy number 7: AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1.
- chr8:35,862,123–36,988,412, 16 genes, copy number 17 (within-gene range 2–17): AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1.
- chr8:67,732,587–69,130,345, 15 genes, copy number 7: AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1.
- chr8:92,882,984–97,149,654, 84 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:99,695,957–104,589,024, 123 genes, copy number 7–16 (broad region; genes not listed).
- chr8:104,699,479–104,703,555, 1 gene, copy number 9: AC012564.1.
- chr8:104,990,308–105,011,568, 2 genes, copy number 12: AC090142.3, AC090142.1.
- chr8:106,215,763–106,981,571, 9 genes, copy number 9: SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1.
- chr8:115,408,496–124,728,473, 129 genes, copy number 8–9 (broad region; genes not listed).
- chr8:142,089,827–143,738,234, 78 genes, copy number 11 (broad region; genes not listed).
- chr11:54,682,877–54,683,821, 1 gene, copy number 8: OR4A8.
- chr13:97,675,011–114,337,626, 271 genes, copy number 8–11 (broad region; genes not listed).
- chr19:29,665,459–33,175,799, 66 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr19:36,573,070–45,873,797, 479 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr19:48,813,018–53,512,687, 346 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 881. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
